Somatic mutation profile of tumor specimen TCGA-B0-5077-01A (aliquot TCGA-B0-5077-01A-01D-1462-08) from TCGA case TCGA-B0-5077, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 77.8 years (28,405 days).
Specimen TCGA-B0-5077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37cf8e0f-646a-408c-b963-978b8db4215d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5077-11A (Solid Tissue Normal), aliquot TCGA-B0-5077-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7a91371-e2f7-46c5-86e7-2345699476c7

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 14, Frame Shift Del 3, Nonsense Mutation 3, In Frame Del 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs5030826, CM941362, CM941363, CM941364, COSV56543026, COSV56543035, COSV56543220, COSV56562588; ClinVar: pathogenic; called by muse, mutect2
- ABCG4 | c.1364G>T p.R455M | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56644931; called by muse, mutect2, varscan2
- ADAM29 | c.2128G>T p.V710F | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV63665964; called by muse, mutect2, varscan2
- ADAMTS19 | c.2605C>T p.R869* | Nonsense Mutation (SNP) | VAF 38/272 reads (14%) | catalogued as rs1278634512, COSV50739896; called by muse, mutect2, varscan2
- ADAT3 | c.983C>G p.S328W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV60191767; called by muse, varscan2
- ANO5 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV61088113; called by muse, mutect2, varscan2
- ARHGEF17 | c.3473T>C p.V1158A | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV55235112; called by muse, mutect2, varscan2
- ARSH | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66963561; called by muse, mutect2, varscan2
- BRCA2 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1340506651, COSV66458642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CA14 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs782544136, COSV52530033; called by muse, mutect2, varscan2
- CELSR3 | c.2949C>G p.I983M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50948857; called by muse, mutect2, varscan2
- CEP57 | c.1321A>T p.K441* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV57689641; called by muse, varscan2
- CEP57 | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1468744386, COSV57689652; called by muse, varscan2
- F12 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as rs1486683301, COSV53692305, COSV99499934; called by muse, varscan2
- FAM83G | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV58760321; called by muse, mutect2, varscan2
- HTR7 | c.1010C>A p.T337N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV53290461; called by muse, mutect2, varscan2
- HYAL2 | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51701074; called by muse, mutect2, varscan2
- IRS1 | c.2309C>A p.S770Y | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59338379; called by muse, varscan2
- ITPRID2 | c.1471A>G p.T491A | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57474540; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as rs760886074, COSV58019454; called by muse, mutect2
- JPH3 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52471427; called by muse, mutect2, varscan2
- KDM5C | c.1775A>T p.E592V | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV64767192; called by muse, mutect2, varscan2
- LOXL2 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs761624027, COSV66692606; called by muse, mutect2, varscan2
- MDN1 | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 79/370 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV65526067; called by muse, mutect2, varscan2
- MRAS | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56673030; called by muse, mutect2, varscan2
- NRXN2 | c.1706T>G p.M569R | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55459241; called by muse, mutect2, varscan2
- OVCH1 | c.1444G>A p.G482S | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.125); catalogued as rs774187935, COSV58965966; called by muse, mutect2, varscan2
- PAGE5 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV56944085; called by muse, mutect2
- PIGM | c.278T>A p.L93H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV63635867; called by muse, mutect2, varscan2
- RAI1 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV55396149; called by muse, mutect2, varscan2
- SLC23A2 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57776528, COSV57777032; called by muse, mutect2, varscan2
- TBC1D3I | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs748502192; called by mutect2, varscan2
- TBX6 | c.811T>A p.F271I | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54222656; called by muse, mutect2, varscan2
- TDP2 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV61968059; called by muse, mutect2, varscan2
- UBQLNL | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | catalogued as rs913044587, COSV66492785; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1148G>C p.G383A | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1480566963, COSV60874920; called by muse, mutect2, varscan2
- ARID2 | c.3131_3150del p.Q1044Pfs*6 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | called by mutect2, pindel, varscan2
- BACE1 | c.520_534del p.S174_G178del | In Frame Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- GHITM | c.781+3_781+10del p.X261_splice | Splice Site (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- LHFPL1 | c.570del p.G191Efs*14 | Frame Shift Del (DEL) | VAF 56/122 reads (46%) | called by mutect2, pindel, varscan2
- MPDZ | c.820_822del p.G274del | In Frame Del (DEL) | VAF 29/98 reads (30%) | called by pindel, varscan2
- TTN | c.4417del p.T1473Lfs*6 (on ENST00000591111; = p.T1427Lfs*6 on NM_003319.4) | Frame Shift Del (DEL) | VAF 33/175 reads (19%) | called by mutect2, pindel, varscan2
- ADAT3 | c.984G>T p.S328= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs374083050, COSV60191777; called by muse, mutect2, varscan2
- CARMIL1 | c.1449C>T p.N483= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV61521122; called by muse, mutect2
- CPSF1 | c.114C>G p.L38= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV52780145; called by muse, mutect2, varscan2
- DBN1 | c.645G>T p.R215= | Silent (SNP) | VAF 81/140 reads (58%) | catalogued as COSV52791428; called by muse, mutect2, varscan2
- DDX24 | c.2385G>T p.L795= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as COSV52574146; called by muse, mutect2, varscan2
- FAT3 | c.11409G>A p.P3803= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as rs770522223, COSV53116780; called by muse, mutect2, varscan2
- NAV3 | c.1008C>G p.S336= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV57081208, COSV57098635; called by muse, mutect2, varscan2
- OR2AE1 | c.180T>C p.Y60= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV60390672; called by muse, mutect2, varscan2
- SURF4 | c.258C>T p.S86= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV64339055; called by muse, mutect2, varscan2
- TNKS | c.84G>T p.P28= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV60063123; called by muse, mutect2, varscan2
- TRIM41 | c.531T>A p.P177= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV59320878; called by muse, mutect2, varscan2
- TTC39B | c.561G>A p.Q187= | Silent (SNP) | VAF 50/168 reads (30%) | catalogued as COSV52612949; called by muse, mutect2, varscan2
- USP43 | c.591A>G p.V197= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53305258; called by muse, mutect2, varscan2
- ZNF518A | c.4110T>C p.F1370= | Silent (SNP) | VAF 61/246 reads (25%) | catalogued as COSV60152432; called by muse, mutect2, varscan2
- ANO7 | c.*2G>A | 3'UTR (SNP) | VAF 23/88 reads (26%) | catalogued as rs201886767, COSV51476362, COSV51479717; called by muse, mutect2, varscan2
